Somatic mutation profile of tumor specimen TCGA-ES-A2HT-01A (aliquot TCGA-ES-A2HT-01A-12D-A183-10) from TCGA case TCGA-ES-A2HT, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 54.8 years (20,023 days).
Specimen TCGA-ES-A2HT-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8b8db5eb-3493-4278-8ab9-2cff265933d4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-ES-A2HT-11A (Solid Tissue Normal), aliquot TCGA-ES-A2HT-11A-11D-A183-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/855dcec7-532e-4dca-af39-9f9aec61df12

The open-access MAF lists 92 somatic variants for this specimen: 59 protein-altering or splice-affecting, 21 silent, 12 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 56, Silent 21, 3'UTR 6, Intron 4, Nonsense Mutation 1, 5'UTR 1, In Frame Ins 1, RNA 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANGPTL8 | c.496C>T p.L166F | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52948537, COSV52949692; called by muse, mutect2, varscan2
- ARID1A | c.3080A>G p.Y1027C | Missense Mutation (SNP) | VAF 57/204 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV61371650; called by muse, mutect2, varscan2
- BNIP5 | c.492C>A p.H164Q | Missense Mutation (SNP) | VAF 30/304 reads (10%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.742); catalogued as COSV71325272; called by muse, mutect2
- BPTF | c.7667C>T p.P2556L | Missense Mutation (SNP) | VAF 26/134 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.084); catalogued as COSV58831237; called by muse, mutect2, varscan2
- BTN3A1 | c.1319A>C p.K440T | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT tolerated (0.14); PolyPhen benign (0.348); catalogued as rs753391625, COSV50024451; called by muse, mutect2, varscan2
- C2orf74 | c.296G>A p.S99N | Missense Mutation (SNP) | VAF 28/88 reads (32%) | SIFT tolerated (0.42); PolyPhen benign (0.026); catalogued as COSV67041406; called by muse, mutect2, varscan2
- CFH | c.3398C>A p.S1133* | Nonsense Mutation (SNP) | VAF 78/601 reads (13%) | catalogued as COSV66405739; called by muse, mutect2, varscan2
- CYP27A1 | c.301G>A p.G101R | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.929); catalogued as COSV51466982; called by muse, mutect2, varscan2
- DGKG | c.1570G>A p.D524N | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53961492; called by muse, mutect2, varscan2
- DHX57 | c.3497T>A p.F1166Y | Missense Mutation (SNP) | VAF 11/82 reads (13%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.994); catalogued as COSV54882382; called by muse, mutect2, varscan2
- DOCK2 | c.5350A>G p.S1784G | Missense Mutation (SNP) | VAF 26/86 reads (30%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.952); catalogued as COSV56941576; called by muse, mutect2, varscan2
- DUSP2 | c.899T>G p.F300C | Missense Mutation (SNP) | VAF 42/162 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56619372; called by muse, mutect2, varscan2
- EHBP1L1 | c.1693G>A p.G565R | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as COSV58571458; called by muse, mutect2, varscan2
- EPG5 | c.1513A>G p.N505D | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.385); catalogued as COSV56344533; called by muse, mutect2, varscan2
- EVPL | c.1288C>A p.Q430K | Missense Mutation (SNP) | VAF 41/132 reads (31%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.549); catalogued as COSV56907288; called by muse, mutect2, varscan2
- FAM76B | c.524A>G p.H175R | Missense Mutation (SNP) | VAF 68/277 reads (25%) | SIFT tolerated (0.44); PolyPhen benign (0.192); catalogued as rs1419396729, COSV62556048; called by muse, mutect2, varscan2
- FAN1 | c.2734A>G p.R912G | Missense Mutation (SNP) | VAF 22/86 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.403); catalogued as COSV62949657; called by muse, mutect2, varscan2
- GABRA1 | c.215T>A p.I72N | Missense Mutation (SNP) | VAF 12/212 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV50098789; called by muse, mutect2
- GNA13 | c.518C>A p.S173Y | Missense Mutation (SNP) | VAF 21/276 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.023); catalogued as COSV71474368; called by muse, mutect2
- GRB7 | c.1434G>T p.K478N | Missense Mutation (SNP) | VAF 23/92 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV58446221; called by muse, mutect2, varscan2
- GUCY1A1 | c.619C>T p.P207S | Missense Mutation (SNP) | VAF 25/89 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV56649075; called by muse, mutect2, varscan2
- HORMAD2 | c.472G>T p.V158F | Missense Mutation (SNP) | VAF 54/205 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.532); catalogued as rs1190774303, COSV60897343; called by muse, mutect2, varscan2
- HR | c.214A>C p.M72L | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0); catalogued as COSV57190576; called by muse, mutect2, varscan2
- HRNR | c.1670G>C p.S557T | Missense Mutation (SNP) | VAF 26/282 reads (9%) | SIFT tolerated (0.25); PolyPhen benign (0.007); catalogued as COSV100913102, COSV64254024, COSV64258673; called by muse, mutect2
- IGBP1P2 | c.1001G>A p.G334D | Missense Mutation (SNP) | VAF 21/325 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs755064024; called by muse, mutect2
- IGSF3 | c.786G>T p.M262I | Missense Mutation (SNP) | VAF 29/116 reads (25%) | SIFT tolerated (0.2); PolyPhen benign (0.349); catalogued as rs1319760707, COSV59585647; called by muse, mutect2, varscan2
- IL1R1 | c.1171T>C p.Y391H | Missense Mutation (SNP) | VAF 188/608 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52104593; called by muse, varscan2
- KLB | c.937A>T p.T313S | Missense Mutation (SNP) | VAF 49/179 reads (27%) | SIFT tolerated (0.79); PolyPhen benign (0.005); catalogued as COSV57300028; called by muse, mutect2, varscan2
- KLHDC10 | c.685A>G p.I229V | Missense Mutation (SNP) | VAF 58/164 reads (35%) | SIFT tolerated (0.43); PolyPhen benign (0.007); catalogued as COSV59050116; called by muse, mutect2, varscan2
- KRTAP4-11 | c.428G>T p.S143I | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.048); catalogued as COSV66948115; called by muse, mutect2, varscan2
- LRP2 | c.1445A>G p.Y482C | Missense Mutation (SNP) | VAF 39/131 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55540609; called by muse, mutect2, varscan2
- MCOLN2 | c.216G>C p.K72N | Missense Mutation (SNP) | VAF 20/113 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52293185; called by muse, mutect2, varscan2
- MED16 | c.155G>A p.R52H | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.293); catalogued as rs1183598721, COSV54123034; called by muse, mutect2, varscan2
- MGAT5B | c.411G>T p.Q137H | Missense Mutation (SNP) | VAF 18/103 reads (17%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.997); catalogued as COSV56924969; called by muse, mutect2, varscan2
- MORN1 | c.956A>G p.D319G | Missense Mutation (SNP) | VAF 32/153 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.057); catalogued as COSV66002552; called by muse, mutect2, varscan2
- ODF3 | c.139C>A p.R47S | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as COSV57292447, COSV57294464; called by muse, mutect2, varscan2
- OR10G2 | c.196A>G p.I66V | Missense Mutation (SNP) | VAF 59/254 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.019); catalogued as COSV73390300; called by muse, mutect2, varscan2
- OSBPL7 | c.838C>A p.L280M | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.996); catalogued as COSV50106596; called by muse, varscan2
- PCDH7 | c.2200G>T p.D734Y | Missense Mutation (SNP) | VAF 35/130 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62336491; called by muse, mutect2, varscan2
- PLAC1 | c.563C>T p.P188L | Missense Mutation (SNP) | VAF 81/117 reads (69%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as COSV63655069; called by muse, mutect2, varscan2
- RYR2 | c.2436A>T p.K812N | Missense Mutation (SNP) | VAF 31/190 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as COSV63661138; called by muse, mutect2, varscan2
- SCRN3 | c.752A>C p.K251T | Missense Mutation (SNP) | VAF 20/72 reads (28%) | SIFT tolerated (0.59); PolyPhen benign (0.258); catalogued as COSV55807100; called by muse, mutect2, varscan2
- SDHA | c.1714A>T p.M572L | Missense Mutation (SNP) | VAF 61/276 reads (22%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.005); catalogued as COSV53765384; called by muse, mutect2, varscan2
- SDHAF3 | c.227C>A p.T76N | Missense Mutation (SNP) | VAF 119/353 reads (34%) | SIFT tolerated (0.28); PolyPhen benign (0.09); catalogued as COSV64490611; called by muse, mutect2, varscan2
- SETD1B | c.749C>A p.T250K | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57348106; called by muse, mutect2, varscan2
- SLC2A2 | c.208A>C p.I70L | Missense Mutation (SNP) | VAF 120/428 reads (28%) | SIFT tolerated (0.83); PolyPhen benign (0.01); catalogued as COSV58584458; called by muse, mutect2, varscan2
- SORCS3 | c.2337G>T p.K779N | Missense Mutation (SNP) | VAF 29/130 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.468); catalogued as COSV63793280; called by muse, mutect2, varscan2
- SPINT2 | c.703G>A p.V235I | Missense Mutation (SNP) | VAF 40/135 reads (30%) | SIFT tolerated (0.32); PolyPhen benign (0.005); catalogued as rs200600070; called by muse, mutect2, varscan2
- TDRD6 | c.2128G>A p.A710T | Missense Mutation (SNP) | VAF 54/179 reads (30%) | SIFT tolerated (0.46); PolyPhen benign (0.003); catalogued as COSV60173836; called by muse, mutect2, varscan2
- TMC2 | c.1857C>G p.D619E | Missense Mutation (SNP) | VAF 61/278 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV62649709; called by muse, mutect2, varscan2
- TRAPPC8 | c.1187G>T p.S396I | Missense Mutation (SNP) | VAF 43/206 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); catalogued as COSV51967072; called by muse, mutect2, varscan2
- TTN | c.53707C>A p.L17903I (on ENST00000591111; = p.L10479I on NM_003319.4) | Missense Mutation (SNP) | VAF 54/180 reads (30%) | PolyPhen probably damaging (0.996); catalogued as COSV59883950; called by muse, mutect2, varscan2
- TXLNB | c.1585A>T p.S529C | Missense Mutation (SNP) | VAF 43/158 reads (27%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.007); catalogued as COSV64443070; called by muse, mutect2, varscan2
- VPS13C | c.92T>G p.I31S | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as COSV51121300; called by muse, varscan2
- ZNF227 | c.670A>C p.K224Q | Missense Mutation (SNP) | VAF 22/74 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV57311199; called by muse, mutect2, varscan2
- ZNF292 | c.998T>C p.L333P | Missense Mutation (SNP) | VAF 42/182 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1374359541, COSV60535509; called by muse, varscan2
- COMMD5 | c.57_74dup p.F24_L25insFGRVSF | In Frame Ins (INS) | VAF 23/59 reads (39%) | called by mutect2, varscan2
- IGBP1P2 | c.1000G>A p.G334S | Missense Mutation (SNP) | VAF 21/328 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); called by muse, mutect2
- KLHL13 | c.518_524del p.F173* | Frame Shift Del (DEL) | VAF 161/243 reads (66%) | called by mutect2, pindel, varscan2
- ANKRD11 | c.6033G>A p.S2011= | Silent (SNP) | VAF 4/40 reads (10%) | catalogued as COSV56362129; called by muse, mutect2
- BAZ2B | c.3363T>G p.L1121= | Silent (SNP) | VAF 31/147 reads (21%) | catalogued as COSV54274822; called by muse, mutect2, varscan2
- C1orf127 | c.1261C>T p.L421= | Silent (SNP) | VAF 24/119 reads (20%) | catalogued as COSV65436379; called by muse, mutect2, varscan2
- CLDN23 | c.279G>T p.L93= | Silent (SNP) | VAF 6/17 reads (35%) | catalogued as COSV67731411; called by muse, mutect2
- CYLC2 | c.648T>C p.D216= | Silent (SNP) | VAF 170/656 reads (26%) | catalogued as rs779686121, COSV66336049, COSV66336535; called by muse, mutect2, varscan2
- DNTTIP2 | c.1203A>G p.E401= | Silent (SNP) | VAF 125/502 reads (25%) | catalogued as COSV63283557; called by muse, mutect2, varscan2
- FAM120B | c.2028T>A p.P676= | Silent (SNP) | VAF 15/43 reads (35%) | catalogued as rs747412214, COSV53001101; called by muse, mutect2, varscan2
- FCRL5 | c.1839C>T p.P613= | Silent (SNP) | VAF 131/201 reads (65%) | catalogued as COSV62511381; called by muse, mutect2, varscan2
- GJB6 | c.258C>A p.T86= | Silent (SNP) | VAF 8/45 reads (18%) | catalogued as COSV53831762; called by muse, mutect2, varscan2
- HDAC9 | c.1186C>T p.L396= | Silent (SNP) | VAF 15/52 reads (29%) | catalogued as COSV67766653; called by muse, mutect2, varscan2
- IRGC | c.189G>A p.S63= | Silent (SNP) | VAF 15/43 reads (35%) | catalogued as rs570958028, COSV54982834, COSV54985454; called by muse, mutect2, varscan2
- LHX8 | c.81C>T p.R27= | Silent (SNP) | VAF 17/78 reads (22%) | catalogued as COSV53954318; called by muse, mutect2, varscan2
- LOXL3 | c.1875T>C p.N625= | Silent (SNP) | VAF 61/265 reads (23%) | catalogued as rs751033818, COSV51206119; called by muse, mutect2, varscan2
- NLRP5 | c.3183C>A p.I1061= | Silent (SNP) | VAF 20/85 reads (24%) | catalogued as COSV66761658, COSV66761991; called by muse, mutect2, varscan2
- POLD1 | c.3285C>T p.L1095= | Silent (SNP) | VAF 46/153 reads (30%) | catalogued as COSV54529534; called by muse, mutect2, varscan2
- PSME4 | c.5052A>G p.K1684= | Silent (SNP) | VAF 46/168 reads (27%) | catalogued as COSV66363052; called by muse, mutect2, varscan2
- SCN2B | c.564G>A p.E188= | Silent (SNP) | VAF 55/195 reads (28%) | catalogued as COSV54050075; called by muse, varscan2
- SERPINA1 | c.1050C>T p.P350= | Silent (SNP) | VAF 6/49 reads (12%) | catalogued as COSV63345330; called by muse, mutect2, varscan2
- TBC1D9B | c.2472C>T p.Y824= | Silent (SNP) | VAF 14/104 reads (13%) | catalogued as COSV62281037; called by muse, mutect2, varscan2
- TTN | c.99882T>C p.P33294= (on ENST00000591111; = p.P25870= on NM_003319.4) | Silent (SNP) | VAF 39/128 reads (30%) | catalogued as COSV59883931; called by muse, mutect2, varscan2
- USP36 | c.2346G>T p.T782= | Silent (SNP) | VAF 22/72 reads (31%) | catalogued as COSV61750103; called by muse, mutect2
- ADO | c.*1001T>C | 3'UTR (SNP) | VAF 25/111 reads (23%) | catalogued as rs541490917, COSV101060473; called by muse, mutect2, varscan2
- ETV1 | c.45+282A>T | Intron (SNP) | VAF 16/406 reads (4%) | called by muse, mutect2
- GGPS1 | c.*227A>G | 3'UTR (SNP) | VAF 132/275 reads (48%) | catalogued as COSV99270525; called by muse, mutect2, varscan2
- H2BP2 | n.1062-424G>A | Intron (SNP) | VAF 177/722 reads (25%) | called by muse, mutect2, varscan2
- IGIP | c.-2389T>G | 5'UTR (SNP) | VAF 34/212 reads (16%) | catalogued as COSV100322953; called by muse, mutect2, varscan2
- MCF2L | c.169+6945G>T | Intron (SNP) | VAF 18/41 reads (44%) | called by muse, mutect2, varscan2
- MYCLP1 | n.993G>A | RNA (SNP) | VAF 90/128 reads (70%) | called by muse, mutect2, varscan2
- PRSS23 | c.*1659A>G | 3'UTR (SNP) | VAF 33/146 reads (23%) | catalogued as COSV99722497; called by muse, mutect2, varscan2
- REPIN1 | c.*819G>A | 3'UTR (SNP) | VAF 18/71 reads (25%) | catalogued as rs995275225, COSV101262659; called by muse, mutect2, varscan2
- SPN | c.*2341C>A | 3'UTR (SNP) | VAF 25/99 reads (25%) | catalogued as COSV100788857; called by muse, mutect2, varscan2
- TRIM41 | c.*593A>G | 3'UTR (SNP) | VAF 48/229 reads (21%) | catalogued as COSV59317363; called by muse, mutect2, varscan2
- VAV3 | c.322-6026G>C | Intron (SNP) | VAF 11/47 reads (23%) | called by muse, mutect2, varscan2
